Gene-level copy-number profile of tumor specimen TCGA-ZF-AA4X-01A from TCGA case TCGA-ZF-AA4X, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 56.3 years (20,579 days).
Specimen TCGA-ZF-AA4X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.926b9fcc-8772-4398-8e61-6fdfe52e3521.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZF-AA4X-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/79a7dc4f-cdb8-494b-9b55-61c2a3b50635

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 693; copy number 2: 7,836; copy number 3: 32,758; copy number 4: 17,485; copy number 5: 828; copy number 7: 41; copy number 11: 118; copy number 21: 5; copy number 23: 49.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZF-AA4X-01A-11D-A38F-01): tumor purity 0.72, ploidy 3.3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 213 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:26,103,416–35,674,544, 213 genes, copy number 7–23 (within-gene range 3–23) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 502. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
